Somatic mutation profile of tumor specimen TCGA-MP-A4TD-01A (aliquot TCGA-MP-A4TD-01A-32D-A25L-08) from TCGA case TCGA-MP-A4TD, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.1 years (25,983 days).
Specimen TCGA-MP-A4TD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c2fc414-420c-4190-941e-26a14a62cfc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4TD-10A (Blood Derived Normal), aliquot TCGA-MP-A4TD-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/902cb049-bebf-4684-8002-eaf909b26323

The open-access MAF lists 88 somatic variants for this specimen: 58 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 25, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 3, Intron 2, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- MYBPC3 | c.1595del p.G532Afs*23 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs730880640, CD092569; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STK11 | c.169del p.E57Kfs*7 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs121913319, CD044165; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA2 | c.3439C>T p.R1147W (on ENST00000614293; = p.R1117W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1195370052, COSV99687417; called by muse, mutect2
- ADAM19 | c.1703G>C p.R568T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99976774; called by muse, mutect2, varscan2
- APAF1 | c.877G>A p.E293K (on ENST00000551964 / NM_181861.2; = p.E282K on NM_001160.3) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100452449; called by muse, mutect2, varscan2
- BICD1 | c.2678T>A p.F893Y | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV99862267; called by muse, mutect2, varscan2
- BRINP1 | c.1448T>G p.F483C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99775084; called by muse, mutect2
- BTBD7 | c.2907A>T p.Q969H | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs537278538, COSV100597690; called by muse, mutect2, varscan2
- C19orf54 | c.470G>C p.R157P | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs200687430, COSV99648627, COSV99648806; called by muse, mutect2, varscan2
- C6orf118 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs367717621, COSV100024685; called by muse, mutect2, varscan2
- CD300LG | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.036); catalogued as rs767557360, COSV53222930; called by muse, mutect2, varscan2
- CHST11 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57997116; called by muse, mutect2, varscan2
- CNOT6L | c.931G>T p.D311Y (on ENST00000504123 / NM_001286790.2; = p.D306Y on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99361639; called by muse, mutect2, varscan2
- CUEDC1 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100804712; called by muse, mutect2, varscan2
- DHRS9 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.152); catalogued as rs1266292418, COSV100513418; called by muse, mutect2, varscan2
- EIPR1 | c.77A>T p.D26V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101181945; called by muse, mutect2, varscan2
- EXOC5 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.133); catalogued as COSV100567040, COSV99049297; called by muse, mutect2, varscan2
- FLG | c.9931G>C p.D3311H | Missense Mutation (SNP) | VAF 166/1059 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100911422; called by muse, mutect2, varscan2
- FMO1 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100707731; called by muse, mutect2, varscan2
- GOLGB1 | c.5229G>T p.Q1743H | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100510646; called by muse, mutect2, varscan2
- GP2 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs767132820, COSV100221381; called by muse, mutect2, varscan2
- GP2 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as COSV100221383, COSV56894631; called by muse, mutect2, varscan2
- GRIK1 | c.2345G>A p.G782E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100516446; called by muse, mutect2, varscan2
- GRIK1 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99064011; called by muse, mutect2, varscan2
- HAO1 | c.722-1G>T p.X241_splice | Splice Site (SNP) | VAF 28/123 reads (23%) | catalogued as COSV101113175; called by muse, mutect2, varscan2
- KCNT2 | c.3340G>T p.E1114* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99652837; called by muse, mutect2, varscan2
- LHX9 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100435776, COSV61326746; called by muse, mutect2, varscan2
- LRP1B | c.10599G>A p.W3533* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV101255203; called by muse, mutect2
- LRP1B | c.10598G>T p.W3533L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as rs1243959943, COSV101252326, COSV67214692; called by muse, mutect2
- LRRC36 | c.147T>A p.F49L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); catalogued as COSV100325944; called by muse, mutect2, varscan2
- LSP1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV100289046; called by muse, mutect2
- MAJIN | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377370396, COSV100104429; called by muse, mutect2, varscan2
- MGAM | c.4969G>C p.G1657R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527444; called by mutect2, varscan2
- MROH9 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV100882733, COSV100882997; called by muse, mutect2, varscan2
- MTUS1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs888588366, COSV100029289; called by muse, mutect2, varscan2
- MX2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.118); catalogued as COSV100415869; called by muse, mutect2, varscan2
- NGEF | c.879C>A p.N293K | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as COSV99888786; called by muse, mutect2
- OR2T1 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV63542717; called by muse, mutect2
- PCMTD1 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100859624; called by muse, mutect2
- PDK2 | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs199817074, COSV50304203; called by muse, mutect2, varscan2
- PPM1B | c.381G>C p.M127I | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56764798, COSV99175747; called by muse, mutect2, varscan2
- PREX2 | c.4740G>T p.L1580F | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236733726, COSV55786410, COSV99906403; called by muse, mutect2
- RABEPK | c.365-2A>C p.X122_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | catalogued as COSV99413340; called by muse, mutect2, varscan2
- SH2D3C | c.2438T>A p.V813E (on ENST00000314830 / NM_170600.3; = p.V656E on NM_005489.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100136722; called by muse, mutect2
- SNTG1 | c.831C>A p.N277K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.146); catalogued as COSV99382929; called by muse, mutect2
- SORBS2 | c.3088C>T p.Q1030* (on ENST00000284776 / NM_021069.5; = p.Q596* on NM_003603.6) | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV99510430; called by muse, mutect2, varscan2
- SPNS1 | c.350A>C p.Y117S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100209021; called by muse, mutect2, varscan2
- STX17 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV99407942; called by muse, mutect2, varscan2
- SVIL | c.4267C>A p.L1423M (on ENST00000355867 / NM_021738.3; = p.L997M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100881186; called by muse, mutect2, varscan2
- SYNDIG1L | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100526448; called by muse, mutect2, varscan2
- SYTL2 | c.1193G>A p.S398N | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs562772705, COSV100314027; called by muse, mutect2, varscan2
- TCHHL1 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV100916520; called by muse, mutect2, varscan2
- TG | c.1728A>T p.E576D | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV99600180; called by muse, mutect2, varscan2
- TRO | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99436185, COSV99436971; called by muse, mutect2, varscan2
- ZXDC | c.1442-1G>T p.X481_splice | Splice Site (SNP) | VAF 28/90 reads (31%) | catalogued as rs1205578338, COSV100306402; called by muse, mutect2, varscan2
- LRRN3 | c.870del p.I291* | Frame Shift Del (DEL) | VAF 28/155 reads (18%) | called by mutect2, pindel, varscan2
- PLAG1 | c.682del p.L228* | Frame Shift Del (DEL) | VAF 22/216 reads (10%) | called by mutect2, pindel, varscan2
- ABCA13 | c.4428A>T p.T1476= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV101330002; called by muse, mutect2
- ADAMTS5 | c.1089C>A p.I363= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as COSV99537396, COSV99537931; called by muse, mutect2
- ANK3 | c.10986A>G p.S3662= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99779387; called by muse, mutect2, varscan2
- ATL3 | c.1512T>C p.D504= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100219793; called by muse, mutect2, varscan2
- CFAP61 | c.2401C>A p.R801= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs555411596, COSV99844291, COSV99844330; called by muse, mutect2, varscan2
- EGFLAM | c.882C>T p.S294= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV100380157; called by muse, mutect2, varscan2
- FGF3 | c.345C>T p.C115= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs116162988, COSV100490153; called by muse, mutect2, varscan2
- GPR1 | c.981G>T p.L327= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV67977816; called by muse, mutect2, varscan2
- HELZ2 | c.2145G>T p.T715= (on ENST00000467148 / NM_001037335.2; = p.T146= on NM_033405.3) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100915527; called by muse, mutect2, varscan2
- HYAL4 | c.1236C>T p.D412= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs201879421, COSV56139321; called by muse, mutect2, varscan2
- IREB2 | c.1869C>T p.A623= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV99359280; called by muse, mutect2, varscan2
- JOSD2 | c.162C>A p.S54= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100975882; called by muse, mutect2, varscan2
- KCNA4 | c.240G>T p.R80= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV100068811; called by muse, mutect2, varscan2
- KLHL38 | c.204G>T p.R68= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as COSV100384338; called by muse, mutect2, varscan2
- MCF2L | c.819G>T p.A273= (on ENST00000375608; = p.A241= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs369640269, COSV100982334; called by muse, mutect2, varscan2
- MMP9 | c.777G>T p.T259= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV100812385; called by muse, mutect2, varscan2
- OLFM1 | c.1383G>T p.L461= (on ENST00000371793 / NM_001282611.2; = p.L443= on NM_014279.5) | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV53283448; called by muse, mutect2
- OR4C15 | c.114C>T p.C38= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as COSV100115567; called by muse, mutect2
- OR5T1 | c.189G>C p.G63= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV100478706, COSV100478876, COSV57302268; called by muse, mutect2
- PACS2 | c.1566G>A p.A522= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as rs782289360, COSV100330684; called by muse, mutect2
- SIGLEC10 | c.1179C>T p.T393= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV59483328; called by muse, mutect2, varscan2
- SOX5 | c.2163T>C p.H721= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as COSV100506555; called by muse, mutect2, varscan2
- SYNDIG1L | c.678G>A p.V226= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV100526450; called by muse, mutect2, varscan2
- UGT2B4 | c.78G>T p.V26= | Silent (SNP) | VAF 10/243 reads (4%) | catalogued as rs1477486311, COSV59316992, COSV59320297; called by muse, mutect2
- UIMC1 | c.1626G>A p.K542= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV101022092; called by muse, mutect2, varscan2
- CDKN2A | c.150+190G>A | Intron (SNP) | VAF 43/181 reads (24%) | called by muse, mutect2, varscan2
- DST | c.4297-1265G>A | Intron (SNP) | VAF 29/162 reads (18%) | catalogued as rs778513837, COSV55003689; called by muse, mutect2, varscan2
- MIR890 | n.60T>C | RNA (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- SLC28A2 | c.*2G>T | 3'UTR (SNP) | VAF 54/256 reads (21%) | catalogued as COSV100754669; called by muse, mutect2, varscan2
- ZNF99 | c.*74A>G | 3'UTR (SNP) | VAF 38/125 reads (30%) | catalogued as COSV101233788; called by muse, mutect2, varscan2
